Gene-level copy-number profile of tumor specimen TCGA-A5-A0G5-01A from TCGA case TCGA-A5-A0G5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.4 years (26,827 days).
Specimen TCGA-A5-A0G5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.83db59b6-adb3-4c1b-b11e-7717a0a23515.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A0G5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97921b81-ed7e-4a5e-b45b-c741e8624427

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 1,401; copy number 2: 30,093; copy number 3: 20,553; copy number 4: 2,959; copy number 5: 2,436; copy number 6: 798; copy number 7: 1,126; copy number 8: 96; copy number 9: 266; copy number 10: 17; copy number 11: 18; copy number 12: 16; copy number 16: 4; copy number 17: 2; copy number 91: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A0G5-01A-11D-A042-01): tumor purity 0.5, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,025,897–246,113,866, 2 genes: AC118555.1, SMYD3-AS1.
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr2:214,241,676–214,684,246, 4 genes (within-gene range 0–2): AC068051.1, RPL5P8, VWC2L, VWC2L-IT1.
- chr6:35,023,522–35,058,015, 2 genes: HSPE1P11, AL591002.1.
- chr7:111,394,875–111,395,043, 1 gene: AC003989.2.
- chr11:28,702,607–29,064,322, 2 genes (within-gene range 0–2): LINC02742, OR2BH1P.
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–2): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,777 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:86,346,824–86,500,259, 5 genes, copy number 5 (within-gene range 3–5): ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1.
- chr1:143,343,180–180,502,954, 1,218 genes, copy number 5 (broad region; genes not listed).
- chr1:191,823,432–192,185,815, 3 genes, copy number 9: LINC02770, AL359081.1, RGS18.
- chr1:192,246,708–192,247,947, 2 genes, copy number 9: AL513175.1, AL513175.2.
- chr3:9,498,361–13,746,638, 106 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:52,046,763–52,250,599, 12 genes, copy number 5: AC115284.3, DUSP7, POC1A, AC097637.3, ALDOAP1, ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M.
- chr3:85,799,987–87,226,277, 13 genes, copy number 5: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795.
- chr3:134,065,303–174,286,644, 606 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:175,059,361–198,222,513, 497 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–1,708,868, 64 genes, copy number 5 (broad region; genes not listed).
- chr5:4,987,789–10,441,792, 118 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:12,553,890–21,341,375, 120 genes, copy number 5–8 (broad region; genes not listed).
- chr5:21,750,673–45,895,970, 342 genes, copy number 6–11 (broad region; genes not listed).
- chr5:75,068,275–77,868,780, 59 genes, copy number 9–12 (within-gene range 2–12): ANKRD31, SUMO2P5, AC008897.2, HMGCR, CERT1, AC008897.3, AC008897.1, POLK, RNU7-175P, AC010245.1, AC010245.2, ANKDD1B, POC5, RNU6-680P, SLC25A5P9, AC108120.3, AC108120.2, BIN2P2, AC108120.1, SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1, SNRPCP2, IQGAP2, AC112173.1, AC026725.1, F2RL2, AC025188.1, AC025188.2, AC025188.3, F2R, F2RL1, RN7SL208P, S100Z, RNU6ATAC36P, CRHBP, AGGF1, AC008581.2, ZBED3, AC008581.1, SNORA47, ZBED3-AS1, AC022414.1, HMGB1P35, PDE8B, ALDH7A1P1, WDR41, RPS2P24, RPL7P23, OTP, TBCA, ACTBP2.
- chr5:151,366,299–151,924,851, 22 genes, copy number 5 (within-gene range 2–5): AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.3, AC011374.1, SPARC, CLMAT3, RN7SKP232, AC011374.2, ATOX1, AC091982.1, RPLP1P6, AC091982.3, G3BP1, GLRA1, AC091982.2, RNA5SP198.
- chr6:14,391,094–14,404,289, 2 genes, copy number 17: AL080313.2, AL080313.1.
- chr6:44,387,706–57,222,307, 193 genes, copy number 6–16 (within-gene range 4–16) (broad region; genes not listed).
- chr8:38,099,471–39,284,917, 38 genes, copy number 5 (within-gene range 3–5): AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10.
- chr8:140,636,281–141,392,574, 18 genes, copy number 5: ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2.
- chr10:10,058,722–38,783,108, 501 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr10:84,138,420–84,518,521, 12 genes, copy number 5 (within-gene range 3–5): AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1.
- chr10:91,765,899–92,353,964, 17 genes, copy number 6: FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1, CPEB3, AL365398.1, SDHCP2, EIF4A1P8, AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12.
- chr11:54,591,480–56,038,191, 64 genes, copy number 7 (broad region; genes not listed).
- chr11:66,616,626–67,683,058, 59 genes, copy number 5 (within-gene range 3–5): RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1, CDK2AP2, CABP2, AP001184.1, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2.
- chr11:102,313,722–102,628,070, 10 genes, copy number 5: RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.
- chr12:71,439,798–71,594,404, 4 genes, copy number 11–91: LGR5, AC090116.1, AC078860.3, AC078860.2.
- chr16:125,737–667,833, 43 genes, copy number 5: Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1, MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1, LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr17:18,244,815–18,363,563, 9 genes, copy number 7: FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778.
- chr17:27,019,527–27,991,787, 36 genes, copy number 6 (within-gene range 4–6): GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3.
- chr17:48,460,370–48,606,414, 8 genes, copy number 5 (within-gene range 2–5): AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2.
- chr18:20,946,906–23,672,748, 61 genes, copy number 6 (broad region; genes not listed).
- chr18:42,649,520–45,181,382, 17 genes, copy number 5: AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1.
- chr18:47,076,117–47,931,146, 20 genes, copy number 6–11 (within-gene range 1–11): AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, AC051635.1, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1.
- chr20:87,250–4,761,696, 149 genes, copy number 5–7 (broad region; genes not listed).
- chr20:16,177,933–16,684,404, 8 genes, copy number 5: AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1.
- chr20:58,389,229–58,850,903, 16 genes, copy number 7 (within-gene range 4–7): VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1.
- chr20:58,842,030–58,842,546, 2 genes, copy number 7: AL132655.7, AL132655.6.
- chr21:10,328,411–17,593,579, 108 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:21,566,763–31,559,977, 170 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:36,986,739–38,121,360, 21 genes, copy number 5 (within-gene range 3–5): Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1.

Autosomal genes at a single copy (total copy number 1): 1,374. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
